Surgical pathology report (de-identified scan), TCGA case TCGA-06-2569, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Henry Ford Hospital, specimen TCGA-06-2569-01A (Primary Tumor).

[page 1 of 3]
CLINICAL HISTORY

has had headaches for about and generalized weakness. On imaging, there is a 4.6 cm superior right frontal mass with T1 central hyperintensity, fluid levels, rim thickened enhancement, and broad attachment to falx.

OPERATIVE DIAGNOSES

Brain tumor-craniotomy

Operation/Specimen: A: Brain, right frontal lesion, biopsy
: Brain, right frontal lesion, biopsy

PATHOLOGICAL DIAGNOSIS:

Brain, right frontal, excisional biopsies:

1. Malignant glioma, pleomorphic, superficial (WHO III).
2. MIB-1 proliferation index: 35%.

See Microscopy Description and Comment.

COMMENT

The neoplasm is a malignant proliferation of spindle/epithelioid cells that have prominent pleomorphism, focally brisk mitotic activity, and a high MIB-1 proliferation index of about 35% throughout. The tumor is superficial, is growing focally in the leptomeningeal space, and has a prominent reticulin network. The tumor heavily infiltrates the brain, at its margins has astrocytic differentiation, and contains numerous eosinophilic granular bodies. Xanthomatous cells are found occasionally.

Overall, the histological features are more consistent with an anaplastic pleomorphic xanthoastrocytoma (PXA), in spite of the paucity of GFAP expression, a feature that has been observed in some PXAs, particularly when transformed into anaplastic tumors. The possibility of this tumor being a gliosarcoma has been considered; however the absence of a clear sarcomatous pattern, microvascular cellular proliferation, and tumor necrosis does not support that diagnosis at this point.

The features in the biopsy may be correlated with clinical, imaging, and operative findings for their final interpretation and patient's follow up.

[page 2 of 3]
INTRA-OPERATIVE CONSULTATION

A.

"Brain, right frontal lesion, biopsy":

1. Touch prep and smears: Spindle cell neoplasm, R/O high histological grade. Touch preparation smears performed at and results reported to the Physician of Record.
2. Frozen sections: Spindle cell neoplasm, sarcomatous pattern. Frozen section performed at and results reported to the Physician of Record. More tissue coming.

GROSS DESCRIPTION

A.

"Right frontal lesion",

Received fresh, four fragments, 1.7 cm in aggregate. Semi firm, glistening, tan. In total, A1 and A2. Frozen tissue A3.

B. Brain, right frontal lesion, biopsy:

FIXATIVE: None. NO. PIECES: 5 tan-pink, soft, glistening tissue fragments. SIZE/VOL: 5 up to 11 mm. CASSETTES: 1,

MICROSCOPIC DESCRIPTION

IMMUNOHISTOCHEMISTRY: The GFAP demonstrates paucity of fibrillary processes in the bulk of the neoplasm, where there are only small islands of gliofibrillogenesis; focally, where the tumor is infiltrative there is also gliofibrillogenesis by the neoplastic cells; these areas are also positive with S100, synaptophysin, MAP2, and NFP. Many cells throughout the tumor are positive with KP1. SMA, HHF35, and CD34 depict leptomenigeal vessel, and a microvasculature devoid of microvascular cellular proliferation. The neoplasm is negative with vimentin, EMA, cytokeratin, desmin, and CD99.

SPECIAL STAINS: The PAS w/wo diastase demonstrates numerous eosinophilic granular bodies. The Snook's reticulum shows rich background of reticulin fibers.

ICD-9(s):

191.9 191.9

Histo Data

Part A: Brain, right frontal lesion, biopsy

Item	Received:	Block	Ordered	Comment
Stain/cnt				
SMA-DA x 1	1			
HHF35-DA x 1	1			

[page 3 of 3]
CD34-DA x 1 1
Desmin-DA x 1 1
immunolab. Enough???
EMA-DA x 1 1
FS H/E x 1 1
mGFAP-DA x 1 1
H/E x 1 1
KeratinSu x 1 1
CAM5.2 x 1 1
KP1-DA x 1 1
MIB1-DA x 1 1
CD99-DA x 1 1
NeuN x 1 1
NF2F11 x 1 1
PAS x 1 1
PAS d x 1 1
Retic x 1 1
S100-DA x 1 1
Synap-DA x 1 1
TPS H/E x 1 1
M Trich x 1 1
Vim-DA x 1 1
H/E x 1 2
H/E x 1 3

There are blanks in

Please also run MAP2

Part B: Brain, right frontal lesion, biopsy

Taken:	Received:
Stain/cnt	Block Ordered Comment
CD34-DA x 1	1
mGFAP-DA x 1	1
H/E x 1	1
21-DA x 1	1
NF2F11 x 1	1
S100-DA x 1	1

Please also run MAP2

*** End of Report ***

Source: NCI Genomic Data Commons file ceded11c-8056-4737-94d5-a883d1271830 (TCGA-06-2569.3713FBA7-46FF-4499-9027-DC719227E0BD.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).